Somatic mutation profile of tumor specimen TCGA-EJ-7314-01A (aliquot TCGA-EJ-7314-01A-31D-2114-08) from TCGA case TCGA-EJ-7314, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.3 years (22,766 days).
Specimen TCGA-EJ-7314-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b307cc0-7e87-4400-9996-0aad43380b39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7314-10A (Blood Derived Normal), aliquot TCGA-EJ-7314-10A-01D-2114-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/227987b9-717e-4824-9010-1aceffd657d0

The open-access MAF lists 38 somatic variants for this specimen: 31 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 23, Silent 7, Frame Shift Del 5, Nonsense Mutation 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATF2 | c.23A>T p.N8I | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs1444053690, COSV51368665; called by muse, mutect2
- BMPR2 | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.03); catalogued as COSV65808685; called by muse, mutect2, varscan2
- DDN | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV100304902, COSV60292318; called by muse, mutect2, varscan2
- EPB42 | c.237C>A p.F79L (on ENST00000441366 / NM_001114134.2; = p.F109L on NM_000119.3) | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.5); catalogued as COSV55749335; called by muse, mutect2
- FCER1A | c.475C>A p.H159N | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs775232956, COSV63666952, COSV63668366; called by muse, mutect2, varscan2
- G3BP2 | c.895C>T p.R299* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as COSV62976035; called by muse, mutect2, varscan2
- HSPA4L | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as rs1275517334, COSV56544855; called by muse, mutect2, varscan2
- JPH2 | c.1210G>T p.A404S | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV65902863; called by muse, mutect2
- LARS1 | c.3389T>G p.V1130G (on ENST00000394434 / NM_020117.11; = p.V1103G on NM_016460.3) | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV50974275; called by muse, mutect2, varscan2
- METTL23 | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 56/181 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57971397; called by muse, mutect2, varscan2
- MSN | c.335A>C p.N112T | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV64303733; called by muse, mutect2, varscan2
- NRK | c.1946G>A p.R649Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs376634125, COSV54593764; called by muse, mutect2, varscan2
- PCDHA8 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV65325437; called by muse, mutect2, varscan2
- PDCL2 | c.185A>G p.D62G | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as COSV55260042; called by muse, mutect2
- PDLIM5 | c.34G>A p.A12T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV58746880; called by muse, mutect2, varscan2
- PDP1 | c.1273C>T p.H425Y | Missense Mutation (SNP) | VAF 7/132 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.852); catalogued as COSV52601047; called by muse, mutect2
- PLEKHH3 | c.2117A>T p.Y706F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV52217315; called by muse, mutect2
- PRTFDC1 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.878); catalogued as rs895278797, COSV60774124; called by muse, mutect2
- PSD4 | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 26/265 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs146593284, COSV55531310; called by muse, mutect2, varscan2
- SEC16B | c.848G>A p.S283N | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV57624836; called by mutect2, varscan2
- SERPIND1 | c.390C>A p.N130K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53138191; called by muse, mutect2, varscan2
- TNIP2 | c.290T>A p.L97Q | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59569157; called by muse, mutect2
- UBE2I | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57646777; called by muse, mutect2
- URB2 | c.1496C>T p.S499F | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.6); PolyPhen benign (0.084); catalogued as COSV50984866; called by muse, mutect2, varscan2
- VAX1 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); catalogued as COSV53328627; called by muse, mutect2
- ASPN | c.487del p.S163Vfs*11 | Frame Shift Del (DEL) | VAF 20/128 reads (16%) | called by mutect2, pindel, varscan2
- CAPSL | c.365del p.K122Sfs*2 | Frame Shift Del (DEL) | VAF 30/97 reads (31%) | called by mutect2, pindel, varscan2
- FABP4 | c.392del p.R131Kfs*11 | Frame Shift Del (DEL) | VAF 17/78 reads (22%) | called by mutect2, pindel, varscan2
- IQGAP2 | c.262_263insTCT p.V87_S88insF | In Frame Ins (INS) | VAF 15/89 reads (17%) | called by mutect2, varscan2
- IQGAP2 | c.265_269del p.E89Kfs*4 | Frame Shift Del (DEL) | VAF 16/90 reads (18%) | called by mutect2, pindel*, varscan2
- MCM3AP | c.2375_2376del p.D792Afs*40 | Frame Shift Del (DEL) | VAF 39/148 reads (26%) | called by mutect2, pindel, varscan2
- ATP2B2 | c.1377G>A p.S459= (on ENST00000352432; = p.S425= on NM_001683.5) | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs556206364, COSV59493755; called by muse, mutect2, varscan2
- JMJD1C | c.4242A>C p.S1414= | Silent (SNP) | VAF 16/188 reads (9%) | catalogued as COSV59514119; called by muse, mutect2
- L1CAM | c.909C>T p.G303= | Silent (SNP) | VAF 50/191 reads (26%) | catalogued as COSV62827674; called by muse, mutect2, varscan2
- MS4A14 | c.90T>C p.P30= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV55729471; called by muse, mutect2
- PTCHD4 | c.2250C>T p.S750= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1400570215, COSV59781874; called by muse, mutect2, varscan2
- TENM1 | c.819C>T p.F273= | Silent (SNP) | VAF 46/73 reads (63%) | catalogued as COSV64429797; called by muse, mutect2, varscan2
- VPS13B | c.10791C>T p.V3597= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV62138785; called by muse, mutect2, varscan2
